Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5333, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5333-01A (Primary Tumor).

[page 1 of 3]
Specimen(s) Received

1. Lymph-Node: Left Neck External Jugular Node
2. Lymph node: Left neck level 4
3. Tonsil: Left tonsil pillar/QS
4. Oral-Cavity: Left retromolar trigone/QS
5. Oral Cavity: Medial tongue margin/QS
6. Oral Cavity: Tongue resection long stitch-anterior; short stitch-medial
7. Neck: Left neck level IA & IB
8. Neck: Left neck level II
9. Neck: Left neck level III & IV
10. Surgical Waste

Diagnosis

1. Left neck external jugular node.

One lymph node negative for tumor (0/1).

2. Left neck level IV.

One lymph node negative for tumor (0/1).

3. Left tonsil pillar.

Negative for tumor.

4. Left retromolar trigone.

Negative for tumor.

5. Medial tongue margin.

Negative for tumor.

6. Oral cavity; tongue; resection.

Spindle cell (sarcomatoid) squamous cell carcinoma, poorly differentiated.

- a. Tumor maximum diameter 3.2 cm.
- b. Tumor thickness 1.0 cm.
- c. No lymphatic/vascular invasion.
- d. No perineural invasion.
- e. Margins negative for tumor.

7. Left neck level IA and IB.

Seven lymph nodes negative for tumor (0/7).

Submandibular gland with no pathologic changes.

[page 2 of 3]
8. Left neck level II.
Eight lymph nodes negative for tumor (0/8).

9. Left neck level III and IV.
Four lymph nodes negative for tumor (0/4).

10. Surgical waste.
Skin and soft tissues with no pathologic changes. (Gross examination only)

Synoptic Data

Specimen Type:	Resection:tongue; resection.
Tumor Site:	Tongue
Histologic Type:	Spindle cell carcinoma
Tumor Size:	Greatest dimension: 3.2 cm Tumor thickness: 1.0 cm
Histologic Grade:	G3: Poorly differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Absent
Margins:	Margins uninvolved by tumor
Pathologic Staging (pTNM):	pT2: Tumor of lip or oral cavity more than 2 cm but not more than 4 cm in greatest dimension pN0: No regional lymph node metastasis for aerodigestive sites Number of regional lymph nodes examined: 21 Number of regional lymph nodes involved: 0 pMX: Distant metastasis cannot be assessed

Clinical History

Oral CA

Gross Description

1. The specimen is labeled with the patient's name and "left external jugular node". It consists of one lymph node measuring 0.8 x 0.5 x 0.4 cm.

1A one lymph node

2. The specimen is labeled with the patient's name and "left neck level IV". It consists of one lymph node measuring 2.6 x 1.5 x 0.9 cm.

2A one lymph node

3. The specimen is labeled with the patient's name and "left tonsil pillar qs". It consists of a fragment of tissue measuring 2.4 x 0.4 x 0.3 cm. The specimen is submitted in toto for frozen section.

3A frozen section control

4. The specimen is labeled with the patient's name and "left retromolar trigone". It consists of a fragment of tissue measuring 1.8 x 0.4 x 0.2 cm. The specimen is submitted in toto for frozen section.

4A frozen section control

5. The specimen is labeled with the patient's name and "medial tongue margin". It consists of a fragment of tissue measuring 4.0 x 1.1 x 0.9 cm. The specimen is bisected and submitted in toto for frozen section.

[page 3 of 3]
5A 5B frozen section control

6. The specimen is labeled the patient's name and "tongue resection long stitch anterior short medial". It consists of an oriented portion of left lateral tongue measuring 4.4 SI x 3.3 ML x 7.7 AP cm. There is a well-circumscribed tumor involving the lateral surface of the tongue. The tumor measures 2.7 SI x 1.0 ML x 3.2 AP cm. The tumor is ulcerated, tan, solid and firm. It is located at 2.2 cm from the lateral/inferior floor of mouth margin, 1.5 cm from the medial/deep soft tissue margin, 2.2 cm from the anterior margin, 1.3 cm away from the superior tongue margin and 3.1 from the posterior margin. The remaining tongue mucosa is grossly unremarkable. Representative sections are submitted.

- 6A anterior tongue resection margin
- 6B posterior tongue resection margin
- 6C superior tongue margin
- 6D inferior/lateral floor of mouth margin
- 6E medial/deep soft tissue margin
- 6F-6H tumor

7. The specimen is labeled with the patient's name and "left neck level IA and level IB". It consists of portion of fibroadipose tissue measuring 8.3 x 4.8 x 2.2 cm. The submandibular gland is unremarkable and measures 4.3 x 3.8 x 1.7 cm. Multiple lymph nodes ranging from 0.6 x 0.4 x 0.4 to 1.3 x 1.0 x 1.0 cm are identified. Representative sections are submitted.

- 7A submandibular gland
- 7B multiple lymph nodes
- 7C one lymph node
- 7D one lymph node

8. The specimen is labeled with the patient's name and "left neck level II". It consists of portion of fibroadipose tissue measuring 5.3 x 2.2 x 1.4 cm. Multiple lymph nodes ranging from 0.5 x 0.3 x 0.3 to 1.3 x 1.0 x 0.8 cm are identified. Representative sections are submitted.

- 8A one lymph node
- 8B two lymph nodes
- 8C one lymph node
- 8D multiple lymph nodes

9. The specimen is labeled with the patient's name and "left level III and level IV". It consists of portion of fibroadipose tissue measuring 3.8 x 1.9 x 1.0 cm. Multiple lymph nodes ranging from 0.4 x 0.2 x 0.3 to 2.1 x 0.6 x 0.6 cm are identified. Representative sections are submitted.

- 9A one lymph node
- 9B multiple lymph nodes
- 9C one lymph node bisected

10. The specimen is labeled with the patient's name and "surgical waste". It contains three unremarkable and unoriented pieces of tan skin with fibroadipose ranging from 4.5 x 0.9 x 0.5 cm to 9.5 x 4.3 x 0.7 cm. No samples are submitted for histologic examination.

Gross Section Diagnosis

3A: Left tonsillar pillar: Negative for malignancy.

4A: Left retromolar trigone: Negative for malignancy.

5A, B: Medial tongue margin: Negative for malignancy.

Source: NCI Genomic Data Commons file 7edf00d7-c261-4426-b462-6f9bdcbaabee (TCGA-CQ-5333.1E3A8A7F-F12E-4DD8-8D91-1095CD3FBE43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).